Surgical pathology report (de-identified scan), TCGA case TCGA-85-7696, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-7696-01A (Primary Tumor).

[page 1 of 2]
Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
					LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 3 x 3 x 3.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
ID	Laterality	Date of procurement
	Left-upper	

Source: NCI Genomic Data Commons file 8e0c530a-2781-4338-a784-a030850bdca7 (TCGA-85-7696.79AD4A6B-D044-483E-AB53-B6D9BADC2F51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).